Surgical pathology report (de-identified scan), TCGA case TCGA-34-2596, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2596-01A (Primary Tumor).

[page 1 of 5]
CLINICAL HISTORY

Not given.

PRE-OP DIAGNOSIS: Lung cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Flexible bronchoscopy/mediastinoscopy.

TL/caa

ADDENDUM

Fluorescence in-situ hybridization studies performed on the squamous cell carcinoma show a ratio of Her2 / Neu to the centromere of chromosome 17 of 1.30, indicating low-level amplification in the targeted region. The ratio of Cyclin-D1 gene to the centromere of chromosome 11 is 1.14, indicating a lack of amplification in the targeted region. The ratio of EGFR gene to the centromere of chromosome 7 is 1.07, indicating an absence of amplification in the targeted region.

Her2 / neu and Cyclin D1 amplification may help in identifying those patients likely to experience shorter survival when considered together with other major risk factors.

Reference:

[REDACTED] et al: Expression of cyclin D1 but not cyclin E is an indicator of poor prognosis in small adenocarcinomas of the lung. Oncol Rep 2003 [REDACTED]

[REDACTED] et al: Trastuzumab in the treatment of non-small cell lung cancer. Semin Oncol (1 Suppl 4):59-65.

[REDACTED] et al: HER2 / neu expression in malignant lung tumors. Semin Oncol (1 Suppl 4):51-8.

[REDACTED] et al: HER2 / neu overexpression in patients with radically resected nonsmall cell lung carcinomas. Impact of long-term survival. [REDACTED] (10):2669-74.

[REDACTED] et al: Evidence for the epidermal growth factor receptor as a target for lung cancer prevention. Clin Cancer Res 2002 [REDACTED]

[REDACTED] Prognostic significance of p21waf1, cyclin D1 and retinoblastoma expression detected by immunohistochemistry in non-small cell lung cancer. Oncol Rep 2001 [REDACTED]:737-42.

FINAL DIAGNOSIS

Summary statement

There is a 4.3 cm invasive, poorly differentiated squamous cell carcinoma in the left main stem bronchus extending into the left upper and lower lobes. There is no evidence of visceral pleural invasion. All surgical resection margins are free of tumor. Metastatic squamous cell carcinoma is present in five (5) fragments of N1 lymph nodes. All sampled N2 lymph nodes are benign. Pathologic stage: T2N1Mx.

PART 1: LYMPH NODE, SUBCARINAL, BIOPSY

TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

[page 2 of 5]
PART 2: LYMPH NODE, LEFT TRACHEOBRONCHIAL ANGLE, BIOPSY
FOUR (4) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 3: LYMPH NODE, SUBINNOMINATE, BIOPSY
FIVE (5) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 4: LYMPH NODE, LEFT PARATRACHEAL, BIOPSY
MINUTE FRAGMENT OF BENIGN LYMPHOID TISSUE.

PART 5: BONE, SIXTH RIB, RESECTION
DECALCIFICATION PENDING. ADDENDUM REPORT TO FOLLOW.

PART 6: LYMPH NODE, INFERIOR PULMONARY LIGAMENT, BIOPSY
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 7: LYMPH NODE, POSTERIOR HILAR, BIOPSY
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 8: LYMPH NODE, ANTERIOR HILAR, BIOPSY
SIX (6) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 9: LYMPH NODE, SUBCARINAL, BIOPSY
TWELVE (12) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 10: LUNG, LEFT, PNEUMONECTOMY
A. INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.3 CM IN DIAMETER). NO EVIDENCE OF VISCERAL PLEURAL INVASION. MILD LYMPHOCYTIC HOST RESPONSE. METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN FIVE (5) OF SEVENTEEN (17) N1 LYMPH NODES. PATHOLOG STAGE: T2 N1 MX.
B. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
C. BACKGROUND LUNG WITH RESPIRATORY BRONCHIOLITIS.

PART 11: LYMPH NODE, AP WINDOW, BIOPSY
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

COMMENT

{Not Entered}

GROSS DESCRIPTION

The specimen is received fresh in eleven parts each labeled with the with the patient' s name and initials

Part 1 is labeled "subcarinal lymph node" and consists of three fragments of black, irregular, fibrofatty tissue ranging from 0.4 to 0.6 cm. The specimen is entirely submitted following intraoperative consultation in cassette 1A.

Part 2 is labeled "left tracheobronchial angle lymph node" and consists of six fragments of irregular, fibrofatty tissue ranging from 0.2 to 0.4 cm. The specimen is submitted entirely following intraoperative consultation in cassette 2A.

Part 3 is labeled "subinnominate lymph node" and consists of five fragments of irregular fibrofatty tissue measuring from 0.4 to 0.6 cm. The specimen is entirely submitted following intraoperative consultation in cassette 3A.

Part 4 is labeled "left paratracheal lymph node" and consists of a single irregular tissue fragment measuring

[page 3 of 5]
0.5 cm. The specimen is entirely submitted following intraoperative consultation in cassette 4A.

Part 5 is labeled "portion of 6th rib" and consists of a 1.5 cm hemorrhagic rib. Representative sections are submitted for decalcification in cassette 5A.

Part 6 is labeled "inferior pulmonary ligament lymph node" and consists of a single 1.0 cm anthracotic lymph node. The specimen is bisected and entirely submitted in cassette 6A.

Part 7 is labeled "posterior hilar lymph node" and consists of a single 0.5 cm anthracotic lymph node. The specimen is entirely submitted in cassette 7A.

Part 8 is labeled "anterior hilar lymph node" and consists of two anthracotic lymph nodes measuring 1.0 and 1.4 cm. The specimen is entirely submitted in cassette 8A.

Part 9 is labeled "subcarinal lymph node" and consists of seven sections of anthracotic tissue ranging in size from 0.5 to 2.0 cm. The specimen is entirely submitted in cassettes 9A through 9C.

Part 10 is labeled "left lung" and consists of a native pneumonectomy specimen measuring 24.0 x 13.0 x 3.0 cm and weighing 470 grams. The pleural surface is tan and hemorrhagic and torn in areas around the lower lobe. The parietal pleura is adherent to the visceral pleura in the upper lobe. The visceral pleura is smooth and glistening. The hilar bronchus is patent at the margin, but obstructed with a mass located 1.8 cm from the margin. The hilar vessels are patent. The hilar lymph nodes are enlarged. On cut surface, the parenchyma is diffusely anthracotic and spongy. A tan tumor measuring 4.3 x 3.7 x 2.0 cm is centrally located involving the upper and lower lobes and the main bronchus. The tumor contains areas of necrosis. The bronchi distal to the tumor are obstructed and contain mucus. The vessels are patent. Multiple hilar lymph nodes grossly containing tumor are seen. Digital images are taken. Representative sections are submitted in the following cassettes:

- 10A - frozen section of bronchial and vascular resection margins
- 10B-10C - hilar lymph nodes
- 10D-10E - tumor with hilar pleura (inked orange)
- 10F-10G - tumor and bronchus
- 10H-10I - lymph nodes with tumor
- 10J-10K - tumor with adjacent lung
- 10L - background lung, upper lobe, with obstruction and cyst
- 10M-10O - lymph nodes

Part 11 is labeled "AP window lymph node" and consists of a single anthracotic lymph node measuring 2.0 cm. The specimen is entirely submitted in cassette 11A.

MICROSCOPIC DESCRIPTION

Microscopic examination substantiates the above diagnosis. Mucicarmine, PAS and PAS with diastase are negative. Elastic stain shows intact visceral pleura.

SYNOPTIC PRIMARY LUNG TUMORS

A. Location: 6

- | | | |
|--------|--------|-------------------------|
| 1. RUL | 3. RLL | 5. LUL |
| 2. RML | 4. LLL | 6. Bronchus intermedius |

B. Procedure: 4

- | | |
|--------------------|------------------|
| 1. Wedge/Segmental | 3. Bilobectomy |
| 2. Lobectomy | 4. Pneumonectomy |

[page 4 of 5]
C. Size of tumor (maximum dimension): 4.3 cm.

D. Satellite nodules: 2

1. Yes 2. No

D1. If yes, Where:

1. Same lobe 2. Ipsilateral lobes 3. Central lobe

D2. Grossly noted:

1. Yes 2. No

D3. Microscopic satellites:

1. Yes 2. No

E. Type: 1

- | | |
|---|---------------------------------------|
| 1. Invasive squamous carcinoma | 11. Fetal type adenocarcinoma |
| 2. Basaloid squamous carcinoma | 12. Small cell carcinoma |
| 3. Invasive adenocarcinoma | 13. Carcinoid |
| 4. Bronchioloalveolar carcinoma, nonmucinous type | 14. Atypical carcinoid |
| 5. Bronchioloalveolar carcinoma, mucinous type | 15. Sarcoma |
| 6. Large cell carcinoma | 16. Adenosquamous carcinoma |
| 7. Clear cell carcinoma | 17. Mixed non-small cell carcinoma, N |
| 8. Giant cell carcinoma | 18. Carcinosarcoma |
| 9. Sarcomatoid carcinoma | 19. Large cell neuroendocrine |
| 10. Blastoma | 20. Other |

F. Architectural grade: 3

1. Well 2. Moderate 3. Poor/undifferentiated

G. Nuclear grade: 3

1. Low 2. Intermediate 3. High

H. Location in lung: 1

1. Central 2. Peripheral

I. Visceral pleural invasion through elastica: 2

1. Yes 2. No

J. Parietal pleural invasion: 2

1. Yes 2. No

K. Chest wall invasion (into skeletal muscle or soft tissue): 2

1. Yes 2. No

L. Angiolymphatic invasion: 1

1. Yes 2. No

M. Necrosis: 1

1. 50% 2. 50%

N. Surgical margins involved: 2

1. Yes 2. No

O. Inflammatory (desmoplastic) reaction: 1

1. Mild 2. Moderate 3. Severe

P. N1 lymph node involvement (N1 nodes): 1

1. Yes 2. No

Q. N1 hilar lymph nodes involved, number of positive lymph nodes: 5

R. Total number of N1 lymph nodes examined: 25

S. Extracapsular spread of N1 lymph node metastases: 2

1. Yes 2. No

T. Mediastinal (N2) nodes involved: 1

1. Yes 2. No 3. Not applicable

U. Mediastinal node group(s) involved (N2 nodes): N/A

- | | | | | | |
|-------------|--------------|-------------|---------------|--------------|--------------|
| 1. Level 4R | 4. Level 7R | 7. Level 4L | 10. Level 7L | 13. Level 2L | 16. Level 2R |
| 2. Level 5R | 5. Level 9R | 8. Level 5L | 11. Level 9L | 14. Level 3L | 17. Level 3R |
| 3. Level 6R | 6. Level 10R | 9. Level 6L | 12. Level 10L | 15. Level 8L | 18. Level 8R |

V. Number of positive mediastinal N2 nodes: 0

W. Total number of mediastinal nodes N2 examined: 24

X. Extracapsular spread of mediastinal lymph node N2 metastases: N/A

[page 5 of 5]
1. Yes 2. No
- Y. Underlying disease(s): 4
- | | | |
|-------------------|--------------------------|-----------------------------------|
| 1. Emphysema | 4. Smokers bronchiolitis | 7. Pneumoconiosis, NOS |
| 2. Bronchiectasis | 5. Asthma | 8. Chronic interstitial pneumonia |
| 3. Tumorlets | 6. Parenchymal scar | 9. Atypical alveolar hyperplasia |
- Z. TNM Stage: T 2 N 1 M x
- ██████

INTRAOPERATIVE DIAGNOSIS

1A: LYMPH NODE, SUBCARINAL, BIOPSY (frozen section)

A. BENIGN.

B. LYMPH NODE FRAGMENTS, NEGATIVE FOR NEOPLASM ██████████

2A: LYMPH NODE, TRACHEOBRONCHIAL ANGLE, BIOPSY (frozen section)

A. BENIGN.

B. LYMPH NODE FRAGMENTS, NEGATIVE FOR MALIGNANCY ██████████

3A: LYMPH NODE, SUBINNOMINATE, BIOPSY (frozen section)

A. BENIGN.

B. ANTHRACOTIC LYMPH NODE FRAGMENTS, NEGATIVE FOR MALIGNANCY ██████████

4A: LYMPH NODE, PARATRACHEAL, LEFT, BIOPSY (frozen section)

A. BENIGN.

B. LYMPH NODE FRAGMENTS, NEGATIVE FOR MALIGNANCY ██████████.

10A: LUNG, LEFT, CHECK BRONCHIAL AND VASCULAR MARGINS (frozen section)

A. BENIGN.

B. BRONCHIAL AND VASCULAR MARGINS OF RESECTION ARE FREE OF NEOPLASM ██████████

██████

Source: NCI Genomic Data Commons file 90aa3c34-1d64-473e-bfd4-3b626bdb18c9 (TCGA-34-2596.03AF2AB8-FAD5-49F6-94D7-8FAAEC71B63F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).